Somatic mutation profile of tumor specimen TCGA-DU-8161-01A (aliquot TCGA-DU-8161-01A-11D-2253-08) from TCGA case TCGA-DU-8161, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 63.1 years (23,064 days).
Specimen TCGA-DU-8161-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 888f7a4f-66b7-403b-9e7c-77d5c077fc0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-8161-10A (Blood Derived Normal), aliquot TCGA-DU-8161-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b8c5045-8a10-427e-ae00-11262d99d62d

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 27, Silent 11, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ2 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs147750704, CM051940; ClinVar: uncertain significance / likely pathogenic / benign; called by muse, mutect2, varscan2
- ANO9 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs770127372, COSV60448499; called by muse, mutect2, varscan2
- ASTN1 | c.3482A>G p.Y1161C | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62492752; called by muse, mutect2, varscan2
- AVPR1A | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs1172409368, COSV54545804; called by muse, mutect2, varscan2
- CGAS | c.1324T>G p.F442V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV64807843; called by muse, mutect2, varscan2
- CHRNB4 | c.1017C>A p.H339Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV55715002; called by muse, mutect2, varscan2
- ENAH | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 130/445 reads (29%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.113); catalogued as rs780546038, COSV52865721; called by muse, mutect2, varscan2
- FBN3 | c.8053G>T p.D2685Y | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV54454956; called by muse, mutect2, varscan2
- FGD5 | c.2900T>C p.L967P | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53238735; called by muse, mutect2, varscan2
- FLT4 | c.2248G>A p.V750M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56100761; called by muse, mutect2
- GLT6D1 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs756561670, COSV65627142; called by muse, mutect2, varscan2
- GPR22 | c.443C>A p.A148E | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51744016; called by muse, mutect2, varscan2
- HAS1 | c.703-1G>A p.X235_splice | Splice Site (SNP) | VAF 11/58 reads (19%) | catalogued as COSV55786477; called by muse, mutect2
- HJURP | c.1398G>C p.M466I | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64978573; called by muse, mutect2, varscan2
- HTR5A | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV55281066, COSV55283141; called by muse, mutect2, varscan2
- IGFL2 | c.241C>G p.L81V (on ENST00000377693 / NM_001135113.2; = p.L92V on NM_001002915.2) | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs1243553097, COSV66616709, COSV66616884; called by muse, mutect2, varscan2
- IGHE | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555456704; called by muse, mutect2, varscan2
- ITLN1 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.28); catalogued as rs571105735, COSV58274383; called by muse, mutect2, varscan2
- NAT2 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs138592670; called by muse, mutect2, varscan2
- OR52E4 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 58/193 reads (30%) | catalogued as rs375049618; called by muse, mutect2, varscan2
- OR52N2 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV57676285; called by muse, mutect2, varscan2
- PCLO | c.6625G>T p.V2209F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.246); catalogued as COSV61616667, COSV61620424; called by muse, varscan2
- POU1F1 | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV60155191; called by muse, mutect2, varscan2
- PRAMEF12 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV63214834; called by muse, mutect2, varscan2
- PTPRC | c.2239G>C p.V747L | Missense Mutation (SNP) | VAF 118/487 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV61407678; called by muse, mutect2, varscan2
- TANGO6 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV55761719; called by muse, mutect2, varscan2
- TEC | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV67403738; called by muse, mutect2, varscan2
- TLR1 | c.2297G>A p.G766D | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1255138533, COSV58303347; called by muse, mutect2, varscan2
- UBQLN3 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs143866662; called by muse, mutect2, varscan2
- ATP1A2 | c.246dup p.T83Hfs*4 | Frame Shift Ins (INS) | VAF 50/273 reads (18%) | called by mutect2, pindel, varscan2
- LILRA1 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PAH | c.595_596insG p.K199Rfs*7 | Frame Shift Ins (INS) | VAF 7/66 reads (11%) | called by mutect2, pindel, varscan2
- ADD2 | c.1476C>G p.P492= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV52456033; called by muse, mutect2, varscan2
- ANKFY1 | c.1557G>C p.L519= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV58915039; called by muse, mutect2, varscan2
- CYP2C8 | c.717T>C p.L239= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV64876247; called by muse, mutect2, varscan2
- ERG | c.1122C>T p.R374= (on ENST00000398919 / NM_001243428.1; = p.R350= on NM_004449.4) | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as rs143039786; called by muse, mutect2, varscan2
- FLVCR2 | c.1041A>G p.G347= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV53161100; called by muse, varscan2
- FTSJ1 | c.243A>G p.P81= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1556967440, COSV50025583; called by muse, mutect2, varscan2
- IL20 | c.42G>A p.A14= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs753265887, COSV65584327; called by muse, mutect2, varscan2
- JCAD | c.3825C>T p.S1275= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs780451132, COSV64758327; called by muse, mutect2, varscan2
- LAS1L | c.381A>G p.S127= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs992864125, COSV56706557; ClinVar: likely benign; called by muse, mutect2, varscan2
- RASGRF1 | c.3330C>T p.I1110= | Silent (SNP) | VAF 32/185 reads (17%) | catalogued as rs542075208, COSV60212323; called by muse, mutect2, varscan2
- TM9SF4 | c.171A>G p.E57= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs1176181566, COSV54105008; called by muse, mutect2, varscan2
